Somatic mutation profile of tumor specimen C3N-01818-02 (aliquot CPT0168270006) from CPTAC case C3N-01818, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.7 years (22,156 days).
Specimen C3N-01818-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a60f595-8230-4290-ab09-fac14703d91b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01818-71 (Blood Derived Normal), aliquot CPT0168320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc33037f-b204-4223-ab67-e0d5da0bcd4e

The open-access MAF lists 91 somatic variants for this specimen: 55 protein-altering or splice-affecting, 21 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 21, Intron 9, RNA 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1, 5'UTR 1, 5'Flank 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 39/119 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 138/271 reads (51%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB1 | c.4619C>T p.T1540M | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs773201018, COSV60102718; called by muse, mutect2, varscan2
- ADGRE2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs751483105, COSV59692041; called by muse, mutect2, varscan2
- ALPG | c.376T>A p.F126I | Missense Mutation (SNP) | VAF 127/424 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV54966265; called by muse, mutect2, varscan2
- CDCA5 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs750342876; called by muse, mutect2
- CDH4 | c.2690A>G p.N897S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776832248; called by muse, mutect2
- CR2 | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100889585; called by muse, mutect2, varscan2
- EPHB6 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 114/434 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs573448355, COSV101235964; called by muse, mutect2, varscan2
- ERMP1 | c.1383G>T p.W461C | Missense Mutation (SNP) | VAF 98/327 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV53037137; called by muse, mutect2, varscan2
- ERVV-2 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 86/255 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1204637162; called by mutect2, varscan2
- FLG | c.8746C>A p.H2916N | Missense Mutation (SNP) | VAF 168/708 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs750188040; called by muse, varscan2
- HECW1 | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101224158; called by muse, mutect2, varscan2
- HRNR | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 160/419 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs148184849; called by muse, mutect2, varscan2
- MAJIN | c.601A>T p.T201S | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.039); catalogued as COSV54164475; called by muse, mutect2, varscan2
- MICAL3 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868594284, COSV99262641; called by muse, mutect2, varscan2
- NOS1 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs201533403, COSV57617949; called by muse, mutect2, varscan2
- NRCAM | c.1077G>A p.A359= (on ENST00000379028 / NM_001371124.1; = p.A353= on NM_005010.4 and 21 other RefSeq transcripts) | Splice Region (SNP) | VAF 18/213 reads (8%) | catalogued as rs772013992; called by muse, mutect2
- OR10Q1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140342625; called by muse, mutect2, varscan2
- POTEE | c.1964T>C p.I655T | Missense Mutation (SNP) | VAF 56/425 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100387156; called by muse, mutect2, varscan2
- SEC16A | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs760444762, COSV99260058; called by muse, mutect2, varscan2
- SLC5A9 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 104/365 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs369664164; called by muse, mutect2, varscan2
- SLITRK6 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1310021586; called by muse, mutect2, varscan2
- TRPC7 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 134/391 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs932646076, COSV61458133; called by muse, mutect2, varscan2
- VKORC1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1389217886; called by muse, mutect2
- AKAP9 | c.11225A>G p.Q3742R (on ENST00000359028; = p.Q3718R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/493 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF11 | c.991A>C p.I331L | Missense Mutation (SNP) | VAF 118/351 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- BTNL9 | c.1377G>T p.E459D | Missense Mutation (SNP) | VAF 13/412 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- CMTR2 | c.2064T>G p.C688W | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDHD1 | c.762A>C p.E254D (on ENST00000323669; = p.E451D on NM_030637.3) | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- DNAAF1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 122/414 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- DPY19L4 | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- FSCN2 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HSP90AB1 | c.1610C>T p.T537I | Missense Mutation (SNP) | VAF 139/553 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNJ12 | c.974A>C p.H325P | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KRTAP16-1 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- LYPD6B | c.265T>C p.Y89H (on ENST00000409029 / NM_001317004.1; = p.Y113H on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MUC4 | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 114/424 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MYO10 | c.1828A>G p.T610A | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- MYRFL | c.2648A>G p.D883G | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2
- NCKAP1 | c.1014G>C p.M338I | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NF1 | c.1192del p.L398Wfs*14 | Frame Shift Del (DEL) | VAF 45/292 reads (15%) | called by mutect2, pindel, varscan2
- NPHP1 | c.982G>T p.A328S (on ENST00000393272 / NM_207181.4; = p.A329S on NM_000272.5) | Missense Mutation (SNP) | VAF 149/493 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NUAK1 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR5AC2 | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAX3 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 57/493 reads (12%) | called by muse, mutect2, varscan2
- PPP5C | c.511+1G>T p.X171_splice | Splice Site (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- RYR3 | c.9834C>G p.N3278K (on ENST00000389232; = p.N3279K on NM_001036.6) | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SCNN1B | c.1587G>A p.W529* | Nonsense Mutation (SNP) | VAF 35/531 reads (7%) | called by muse, mutect2
- SETD1A | c.2485A>T p.S829C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.43); called by muse, varscan2
- SLAIN1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 154/264 reads (58%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- SLC6A2 | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 79/519 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SYMPK | c.2858A>G p.D953G | Missense Mutation (SNP) | VAF 231/630 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SYNE2 | c.3822A>G p.I1274M | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TBXAS1 | c.1550A>T p.K517I | Missense Mutation (SNP) | VAF 160/695 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DEPDC1B | c.1239C>T p.V413= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2
- DICER1 | c.4797G>T p.R1599= | Silent (SNP) | VAF 19/406 reads (5%) | catalogued as COSV58624297; called by muse, mutect2
- FAT2 | c.2031A>C p.T677= | Silent (SNP) | VAF 31/281 reads (11%) | called by muse, mutect2, varscan2
- FN1 | c.4473C>G p.V1491= | Silent (SNP) | VAF 10/225 reads (4%) | called by muse, mutect2
- GJA3 | c.639G>A p.A213= | Silent (SNP) | VAF 255/472 reads (54%) | called by muse, mutect2, varscan2
- GOLGA6C | c.558G>A p.E186= | Silent (SNP) | VAF 148/626 reads (24%) | catalogued as rs1306987595, COSV100316489; called by mutect2, varscan2
- KCNH3 | c.1053G>C p.R351= | Silent (SNP) | VAF 106/346 reads (31%) | called by muse, varscan2
- LRRC53 | c.291G>A p.S97= | Silent (SNP) | VAF 20/539 reads (4%) | catalogued as rs1213264983; called by muse, mutect2
- MAGEA12 | c.696T>C p.D232= | Silent (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- NRXN1 | c.1470C>T p.F490= | Silent (SNP) | VAF 154/520 reads (30%) | catalogued as COSV100456647, COSV58458612; called by muse, mutect2, varscan2
- RELN | c.6594T>C p.S2198= | Silent (SNP) | VAF 112/468 reads (24%) | called by muse, mutect2, varscan2
- RELN | c.939C>A p.L313= | Silent (SNP) | VAF 132/564 reads (23%) | called by muse, mutect2, varscan2
- RYR2 | c.3147C>T p.S1049= | Silent (SNP) | VAF 76/209 reads (36%) | called by muse, mutect2, varscan2
- SLC6A6 | c.966G>A p.S322= | Silent (SNP) | VAF 59/206 reads (29%) | catalogued as rs201578085, COSV62647865; called by muse, mutect2, varscan2
- SLC9A2 | c.777G>A p.S259= | Silent (SNP) | VAF 52/176 reads (30%) | catalogued as rs1376781792; called by muse, mutect2
- TMEM108 | c.1080C>T p.T360= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as rs777408703; called by muse, mutect2
- TNFRSF11A | c.87G>A p.Q29= | Silent (SNP) | VAF 191/581 reads (33%) | catalogued as COSV54024765; called by muse, mutect2, varscan2
- UPK1B | c.111A>T p.V37= | Silent (SNP) | VAF 174/535 reads (33%) | called by muse, mutect2, varscan2
- ZNF521 | c.1818C>G p.P606= | Silent (SNP) | VAF 69/230 reads (30%) | called by muse, mutect2, varscan2
- ZNF716 | c.1203T>G p.T401= | Silent (SNP) | VAF 95/376 reads (25%) | called by muse, varscan2
- ZNF780B | c.1863C>G p.A621= | Silent (SNP) | VAF 54/201 reads (27%) | catalogued as COSV55467888; called by muse, mutect2, varscan2
- AC107023.1 | n.25+7101C>T | Intron (SNP) | VAF 60/162 reads (37%) | catalogued as rs1219136684; called by muse, mutect2, varscan2
- ACP5 | c.1-39C>T | Intron (SNP) | VAF 28/246 reads (11%) | called by muse, mutect2, varscan2
- ANAPC1P5 | n.459T>A | RNA (SNP) | VAF 58/455 reads (13%) | called by muse, mutect2, varscan2
- CIZ1 | c.2032-114T>C | Intron (SNP) | VAF 113/326 reads (35%) | called by muse, mutect2, varscan2
- CR2 | c.446-12G>T | Intron (SNP) | VAF 121/419 reads (29%) | catalogued as rs985682133; called by muse, mutect2, varscan2
- EYS | c.1767-7745G>T | Intron (SNP) | VAF 15/82 reads (18%) | called by mutect2, varscan2
- FAM27E5 | n.167C>G | RNA (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- GSC | c.-17C>T | 5'UTR (SNP) | VAF 93/145 reads (64%) | catalogued as rs1308354491; called by muse, mutect2, varscan2
- KLK1 | chr19:50818564 C>G | 3'Flank (SNP) | VAF 18/72 reads (25%) | catalogued as rs1448034506; called by muse, mutect2, varscan2
- PADI4 | c.340+510T>A | Intron (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4760G>A | Intron (SNP) | VAF 133/374 reads (36%) | catalogued as rs782500346, COSV56560140; called by muse, mutect2, varscan2
- PPARG | c.819+82C>T | Intron (SNP) | VAF 50/135 reads (37%) | catalogued as rs760049355; called by muse, mutect2, varscan2
- RN7SL319P | chr15:75780641 G>T | 5'Flank (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- TTLL3 | c.745-1491G>T | Intron (SNP) | VAF 15/326 reads (5%) | called by muse, mutect2
- TUBBP5 | n.933T>A | RNA (SNP) | VAF 38/489 reads (8%) | called by muse, varscan2
